Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A6EG, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A6EG-06A (Metastatic).

ICD-O-3
Melanoma, malignant NOS
Site C49.9
Subcutaneous tissue NOS
path Inguinal lymph node
C77.4
8720/3
C49.9
C77.4
9/26/13

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Skin melanoma of the lumbar region – status post resection and right inguinal lymphadenectomy. Recurrence.**

Date of admission: (urgency: Standard)

Material:

- 1) Material: lymph nodes - inguinal lymph nodes. Nodal recurrence in the inguinal region. Method of collection: Partial organ resection
- 2) Material: skin of the back, recurrence laterally to the right edge of the scar (lumbosacral region). Method of collection: Lesion resection.

Histopathological diagnosis

Examination performed on:

- 1/ Local recurrence of malignant melanoma.
- 2/ Local recurrence of malignant melanoma. (8720/3 T-08810)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

- 1/ Surgical specimen sized 7.0 x 4.5 x 4.0cm with a skin flap sized 5.0 x 2.5cm.
In the cross section tumour sized 4.5 x 2.0 x 2.0cm (margins of 0.1cm).
- 2/ Skin specimens 4.3 x 2.0 x 1.5cm.
In the cross section tumour sized 1.5 x 1.0 x 1.5cm (margins of 0.1 cm).

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Discrepancy: Primary/Not		✓

Source: NCI Genomic Data Commons file d1eeb8b4-80a9-4033-9f78-eaf1582cad53 (TCGA-D9-A6EG.13D80C78-FF04-4168-8592-CAC94E7EE1DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).